Somatic mutation profile of tumor specimen BLGSP-71-19-00120-09A.1 (aliquot BLGSP-71-19-00120-09A.1-01W-A758-33) from CGCI case BLGSP-71-19-00120, project CGCI-BLGSP (Burkitt Lymphoma Genome Sequencing Project). Sex at birth: female; Vital status: Alive; Primary diagnosis: Burkitt lymphoma, NOS (Includes all variants); Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 3.3 years (1,214 days).
Specimen BLGSP-71-19-00120-09A.1: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Sorted Cells; Biospecimen anatomic site: Bone Marrow; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b3f50bc0-213c-4ec8-ab76-186db84bb69d.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BLGSP-71-19-00120-16A (Mononuclear Cells from Bone Marrow Normal), aliquot BLGSP-71-19-00120-16A-01D-A758-33; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ddce9287-53ba-4c05-a772-48612f4ade3f

The open-access MAF lists 8 somatic variants for this specimen: 5 protein-altering or splice-affecting, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, 5'UTR 2, Nonsense Mutation 2, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ID3 | c.202G>A p.E68K | Missense Mutation (SNP) | VAF 42/116 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101000790, COSV65801518; called by muse, varscan2
- CHD8 | c.2706T>A p.Y902* (on ENST00000646647 / NM_001170629.2; = p.Y623* on NM_020920.4) | Nonsense Mutation (SNP) | VAF 158/568 reads (28%) | called by muse, mutect2, varscan2
- H2AC17 | c.285C>G p.N95K | Missense Mutation (SNP) | VAF 114/264 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.706); called by muse, mutect2, varscan2
- TFAP4 | c.130C>T p.Q44* | Nonsense Mutation (SNP) | VAF 18/30 reads (60%) | called by muse, mutect2, varscan2
- XIRP2 | c.8078A>C p.N2693T (on ENST00000628543; = p.N2868T on NM_152381.6) | Missense Mutation (SNP) | VAF 311/725 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- MYC | chr8:127735592 T>C | 5'Flank (SNP) | VAF 456/972 reads (47%) | called by muse, mutect2, varscan2
- MYC | c.-28A>T | 5'UTR (SNP) | VAF 177/472 reads (38%) | catalogued as COSV52369249; called by muse, mutect2, varscan2
- PAX5 | c.-214C>G | 5'UTR (SNP) | VAF 245/598 reads (41%) | catalogued as rs111234296; called by muse, mutect2, varscan2
